Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4YU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4YU-01A (Primary Tumor).

Patient: XXX

PESEL: : XXX

Age:

Gender: M

Examination result No.

Unit in charge: t

Physician in charge:

ef. no.

Clinical diagnosis (suspicion): **malignancy of the stomach - Stomach, undefined - Gastric cancer.** ICD-O-3

Date of admission: (urgency: Standard)

Adenocarcinoma, tubular 8211/3
COP Site: Stomach, fundus C14.1
Path Stomach, NOS C14.9

Material:

1) Material: stomach, Method of collection: Total organ resection

hw, 14/12

Histopathological Diagnosis:

Examination performed on:

(5% per Tss)
Tubular and partially mucinous adenocarcinoma of the stomach. Cancer metastases in the lymph nodes NO XI/XXV. G3, pT3, pN3a Mixed type sec (8140/3 T-63000)*

Macroscopic description:

The specimen containing the stomach, after being incised along the greater curvature sized: 21.5 x 11 cm with the omentum sized: 40 x 23 cm.

Ulcerous tumour in the region of the lesser curvature sized 5.5 x 1.2 x 1.1 cm. Distance from the proximal end: 1.5 cm, from distal end: 9.5 cm.

Another, elevated tumour in the greater curvature region. 3.5 x 2.3 x 1.5 cm, 5.5 cm from the proximal line and 6.5 cm from the distal line.

Microscopic description:

Adenocarcinoma tubulare partim mucocellulare G3 bifocale.

Tumour penetrates the full thickness of the stomach wall and perigastric fat tissue.

Surgical incision lines and the omentum free of neoplastic lesions.

Signs of vascular invasion.

Lymph nodes:

- lesser curvature: metastases carcinomatosae in lymphonodis NO V/XII. Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.
- greater curvature: metastases carcinomatosae in lymphonodis No IV/VIII. Infiltratio carcinomatosa capsulae lymphonodorum. peripyloric: metastases carcinomatosae in lymphonodis No II/V. Infiltratio carcinomatosa capsulae lymphonodorum.

Assistant:

Pathologist:

Edited by:

Result of immunohistochemical examination:

Examination performed on:

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

Negative reaction in invasive cancerous cells (Score = 0)

Assistant:

Pathologist:

Edited by:

CONTACT YOUR DOCTOR WITH THIS

HI/FAA Discrepancy		
Reviewed by	Date Evaluated	

11/2/12

Source: NCI Genomic Data Commons file a5c0ffa9-0a87-47bd-9850-18b451895a57 (TCGA-D7-A4YU.DF435B0E-B010-4911-9123-4AECDA1B0EDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).